Somatic mutation profile of tumor specimen TARGET-10-PARJNX-09A (aliquot TARGET-10-PARJNX-09A-01D) from TARGET case TARGET-10-PARJNX, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.1 years (1,131 days).
Specimen TARGET-10-PARJNX-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1ea70a2a-fe24-4838-b755-e0575b550831.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARJNX-14A (Bone Marrow Normal), aliquot TARGET-10-PARJNX-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/54965c20-e282-4038-9cba-c656308406cf

The open-access MAF lists 15 somatic variants for this specimen: 13 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 9, Silent 2, Frame Shift Del 2, Nonsense Mutation 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1393C>T p.R465C (on ENST00000281708 / NM_001349798.2; = p.R385C on NM_018315.5) | Missense Mutation (SNP) | VAF 44/106 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867384286, COSV55891008, COSV55897912, COSV99654845; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- DNA2 | c.1777G>T p.D593Y | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.429); catalogued as COSV100622686, COSV64429223; called by muse, mutect2, varscan2
- FAM200A | c.362C>T p.T121M | Missense Mutation (SNP) | VAF 60/137 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.953); catalogued as rs546433268, COSV68808863; called by muse, mutect2, varscan2
- GRIN2C | c.1606G>T p.A536S | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.44); PolyPhen benign (0.006); catalogued as COSV53115506; called by muse, mutect2
- NOTCH1 | c.4775T>C p.F1592S | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53024854, COSV53033159; called by muse, mutect2, varscan2
- PATZ1 | c.1093C>A p.R365S | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.994); catalogued as COSV53230218; called by muse, mutect2, varscan2
- PCDH15 | c.3226G>T p.E1076* | Nonsense Mutation (SNP) | VAF 7/157 reads (4%) | catalogued as rs868723522; called by muse, mutect2
- SMARCA4 | c.2738C>T p.P913L | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs778175819, COSV60785488, COSV60786996; called by muse, mutect2, varscan2
- UGDH | c.56C>T p.T19I | Missense Mutation (SNP) | VAF 93/193 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57098873; called by muse, mutect2, varscan2
- GARRE1 | c.2857_2858insAGGGT p.T953Kfs*16 | Frame Shift Ins (INS) | VAF 24/56 reads (43%) | called by mutect2, pindel*, varscan2
- SERPINB7 | c.914C>A p.A305E | Missense Mutation (SNP) | VAF 7/161 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- TRAJ42 | c.1del p.N2Ifs*? | Frame Shift Del (DEL) | VAF 19/30 reads (63%) | called by pindel*, varscan2
- TRAJ58 | c.49del p.L17Pfs*? | Frame Shift Del (DEL) | VAF 20/21 reads (95%) | called by mutect2, pindel*, varscan2
- NMRK2 | c.672G>A p.A224= | Silent (SNP) | VAF 11/18 reads (61%) | catalogued as rs547115351; called by muse, varscan2
- NOTCH1 | c.4776C>T p.F1592= | Silent (SNP) | VAF 6/17 reads (35%) | catalogued as rs752861485, COSV53033213, COSV53038817, COSV53057758, COSV53058307, COSV53062175; called by muse, mutect2, varscan2
